Somatic mutation profile of tumor specimen TCGA-EL-A3ZR-01A (aliquot TCGA-EL-A3ZR-01A-11D-A23M-08) from TCGA case TCGA-EL-A3ZR, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 46.1 years (16,852 days).
Specimen TCGA-EL-A3ZR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3ec3d2e-67fc-4147-8deb-fea47ebcb630.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3ZR-11A (Solid Tissue Normal), aliquot TCGA-EL-A3ZR-11A-11D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8a50b9a-4645-4b4d-97c0-e77f8af4ddc1

The open-access MAF lists 17 somatic variants for this specimen: 10 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 9, Silent 7, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 91/165 reads (55%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABO | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.131); catalogued as rs782321646, COSV71743404; called by muse, mutect2, varscan2
- BNC2 | c.1720A>G p.R574G | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66140109; called by muse, mutect2, varscan2
- KBTBD7 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.869); catalogued as COSV65266559; called by muse, mutect2, varscan2
- KBTBD7 | c.274G>C p.A92P | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV101068119; called by muse, mutect2, varscan2
- LRP10 | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 38/121 reads (31%) | catalogued as COSV62077593; called by muse, mutect2, varscan2
- PCDH11X | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.13); catalogued as rs761488640, COSV53438348; called by mutect2, varscan2
- PLCB3 | c.1771T>G p.S591A | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54185459; called by muse, mutect2
- RDH14 | c.787T>A p.L263M | Missense Mutation (SNP) | VAF 51/195 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.798); catalogued as COSV67118740; called by muse, mutect2, varscan2
- RFXAP | c.662C>A p.P221H | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV55225366; called by muse, mutect2, varscan2
- EPC2 | c.1671T>G p.V557= | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as COSV51539447; called by muse, mutect2, varscan2
- MAP3K15 | c.3147G>A p.K1049= | Silent (SNP) | VAF 42/108 reads (39%) | catalogued as COSV58825402; called by muse, mutect2, varscan2
- NLRP4 | c.2136G>A p.R712= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as rs1267265465, COSV56707111; called by muse, mutect2
- OR5B17 | c.363C>T p.Y121= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as rs146597451; called by muse, mutect2, varscan2
- POMGNT1 | c.111A>G p.R37= | Silent (SNP) | VAF 32/112 reads (29%) | catalogued as COSV64339255; called by muse, mutect2, varscan2
- PPP1R3B | c.487A>C p.R163= | Silent (SNP) | VAF 83/173 reads (48%) | catalogued as COSV60098843; called by muse, mutect2, varscan2
- RSPH14 | c.933G>A p.T311= | Silent (SNP) | VAF 42/191 reads (22%) | catalogued as rs533095411, COSV53266551; called by muse, mutect2, varscan2
